Somatic mutation profile of tumor specimen MP2PRT-PASVFY-TMP1-A (aliquot MP2PRT-PASVFY-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PASVFY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,514 days).
Specimen MP2PRT-PASVFY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72cb4b88-ce39-49a7-91c8-f41369fa8a30.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASVFY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASVFY-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/07b6c535-54f4-4c52-9136-e934e31cc294

The open-access MAF lists 21 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, Nonsense Mutation 2, Intron 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 182/383 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TGFB2 | c.895C>T p.R299W | Missense Mutation (SNP) | VAF 239/463 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs863223792, CM126585; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AQP6 | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 212/476 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs779784128; called by muse, varscan2
- DCAF8L2 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 26/348 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV70549167; called by muse, mutect2
- KIFAP3 | c.70G>T p.E24* | Nonsense Mutation (SNP) | VAF 13/324 reads (4%) | catalogued as COSV63033643; called by muse, mutect2
- MTOR | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 167/326 reads (51%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1226783220, COSV63868961, COSV63869925; called by muse, mutect2, varscan2
- PCDHA5 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 180/481 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.624); catalogued as COSV100972166; called by muse, mutect2, varscan2
- RBFOX2 | c.775C>T p.R259C (on ENST00000438146 / NM_001349995.2; = p.R189C on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53264194; called by muse, mutect2, varscan2
- SOX9 | c.1080_1100del p.P362_Q368del | In Frame Del (DEL) | VAF 194/676 reads (29%) | catalogued as rs772713612; called by mutect2, varscan2
- UBE2O | c.1896G>A p.E632= | Splice Region (SNP) | VAF 72/216 reads (33%) | catalogued as rs1328289220; called by muse, mutect2, varscan2
- WFS1 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 24/690 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.11); catalogued as rs1040106557; called by muse, mutect2
- ZSWIM2 | c.1709C>A p.S570* | Nonsense Mutation (SNP) | VAF 14/257 reads (5%) | catalogued as rs1187711168; called by muse, mutect2
- ACTA2 | c.776G>T p.C259F | Missense Mutation (SNP) | VAF 31/252 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- GRIA3 | c.607A>G p.R203G | Missense Mutation (SNP) | VAF 21/351 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.234); called by muse, mutect2
- MAGI1 | c.2753G>T p.S918I (on ENST00000402939 / NM_001033057.2; = p.S946I on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 193/431 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- ZNF488 | c.503A>G p.K168R | Missense Mutation (SNP) | VAF 178/415 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- FAT4 | c.13002T>G p.T4334= | Silent (SNP) | VAF 133/329 reads (40%) | catalogued as COSV100628482; called by muse, mutect2, varscan2
- OR8K3 | c.285T>C p.Y95= | Silent (SNP) | VAF 114/249 reads (46%) | called by muse, mutect2, varscan2
- SETBP1 | c.3882C>T p.D1294= | Silent (SNP) | VAF 135/365 reads (37%) | catalogued as rs762673953; called by muse, mutect2, varscan2
- TAS1R2 | c.1872G>A p.P624= | Silent (SNP) | VAF 59/565 reads (10%) | catalogued as rs112760365, COSV64747352; called by muse, mutect2, varscan2
- BZW1 | c.-11+438C>A | Intron (SNP) | VAF 170/510 reads (33%) | called by muse, varscan2
